Surgical pathology report (de-identified scan), TCGA case TCGA-CF-A9FL, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ILSBio, specimen TCGA-CF-A9FL-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report (For Collection of Cancerous Tissue) *CLF*

ICD-0-3

Carcinoma papillary urothelial cell NOS 8130/3
with Carcinoma papillary transitional cell 8130/3
Site: Bladder wall NOS C67.9
Q10 4/17/14

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
		☐ Single ☒ Married	Vietnamese	
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☒ Male ☐ Female				

HISTORY OF PRESENT ILLNESS
Chief Complaints: Hematuria
Symptoms: Patient had hematuria for months. No treatment, no fever and dysuria
Clinical Findings: Soft belly, no mass, no peripheral lymph nodes.
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
Appendicitis		Surgery	
Gastrectomy			
Testis haemid		Surgery	
Prostate tumor - per ISS benign		Surgery	

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other:		☐ Hormone Replacement Therapy:

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO	NA		(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☐ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
	NA	

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:		
Hep B	☒ Negative ☐ Positive:		CA 15-3	☐ Negative ☐ Positive:		
Hep C	☐ Negative ☐ Positive:		CA 19-9	☐ Negative ☐ Positive:		
AFP	☐ Negative ☐ Positive:		PSA	☐ Negative ☐ Positive:		
Other:	☐ Negative ☐ Positive:		Other:	☐ Negative ☐ Positive:		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	Suspected extensive bladder cancer	
X-Ray	Normal chest X-ray	
CT	Suspected extensive bladder cancer, invade left ureter	
Endoscopy	bladder cancer	
MRI		
Biopsy	Transitional cell carcinoma, low grade	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Bladder cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T _{4A} N ₀ M ₀ Stage: III		

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
Cystectomy		
Primary Tumor		
Organ	Detailed Location	Size
Bladder		7 x 5 x cm
Extension of Tumor		
Muscular wall of bladder.		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes	NO	
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
NO		
Surgical Staging		
T _{4A}	N ₀	M ₀
Stage: III		

NEOADJUVANT THERAPY (Chem, Radiation, Immun, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
NO				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
✓	✓	✓	✓			✓	✓
Time to LN2		Time to Formalin		Time to LN2			
10 min		10 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Bladder	7 x 5 x cm	Muscle layer of bladder	cm
Lymph Nodes			
Location	# Examined	# Metastasized	
NO			
Distant Metastasis			
Organ	Detailed Location	Size	
NO			
Pathological Staging			
pT 38		N 0	M 0
		Stage: III	
Notes:			

[page 5 of 5]
Consolidated Pathology Diagnosis

ID#: _____

Histological Pattern											
Cell Distribution			Structural Pattern								
	+	-		+	-		+	-		+	-
Diffuse		☒	Streaming								
Mosaic	☒		Storiform								
Necrosis	☒		Fibrosis								
Lymphocytic Infiltration	☒		Palisading								
Vascular Invasion		☒	Cystic Degeneration								
Clusterized	☒		Bleeding								
Alveolar Formation		☒	Myxoid Change								
Indian File		☒	Psammoma/Calcification								

Cellular Differentiation											
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
	+	-		+	-		+	-		+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation: ☐ Well ☒ Moderate ☐ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis			☒	
Hyperchromatism			☒	
Nucleolar Prominent			☒	
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	

Nuclear Grade: ☐ 0 ☒ I ☐ II ☐ III

Final Pathology Report

Histological Diagnosis: papillary transitional cell carcinoma Grade: 2

Comments:

Director, Research Pathology

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS -

Source: NCI Genomic Data Commons file 16c29556-b120-430a-b52a-0829abcecbc2 (TCGA-CF-A9FL.1B45E29B-BFF5-4A16-A378-3ECD312DFE2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).